CCDI case PBCPJI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/579b0304-3ee5-4406-8e0e-f26b2fea38f4

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ewing sarcoma: ICD-O-3 morphology code: 9260/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 17.3 years (6,335 days).

Biospecimens (3 samples)
- Sample 0DWVEJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DWVEX, 0DWVGO (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
